Somatic mutation profile of tumor specimen PCProject_0100_T1_WES (aliquot PCProject_0100_T1_WES_1) from CMI case PCProject_0100, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.6 years (21,037 days).
Specimen PCProject_0100_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46ad9432-96b3-40ed-801b-21c9a3172c88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0100_SALIVA (DNA), aliquot PCProject_0100_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/388fcd00-159a-411b-8239-a8b8fc53cd37

The open-access MAF lists 32 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Intron 2, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 129/618 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMY1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 39/933 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs201967863, COSV64407042; called by muse, mutect2
- CALCR | c.1319G>A p.R440H (on ENST00000649521 / NM_001164737.2; = p.R424H on NM_001742.4) | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs748926357, COSV64005918; called by muse, mutect2, varscan2
- CFAP157 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 150/662 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs766128866; called by muse, mutect2, varscan2
- NCAN | c.2612C>T p.T871M | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs145824706; called by muse, mutect2, varscan2
- SLC16A2 | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.322); catalogued as COSV99330376; called by muse, mutect2
- TBX5 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201637366, COSV100090595; called by muse, mutect2, varscan2
- TMEM259 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1356209439; called by muse, mutect2, varscan2
- CEP350 | c.1924A>T p.K642* | Nonsense Mutation (SNP) | VAF 31/272 reads (11%) | called by muse, mutect2, varscan2
- GOLM2 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPS2 | c.541del p.Q181Kfs*164 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- MYO18B | c.7482G>C p.K2494N | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- NAGLU | c.384-6C>G | Splice Region (SNP) | VAF 111/618 reads (18%) | called by muse, mutect2, varscan2
- NOA1 | c.568C>G p.R190G | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- OR5F1 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- P2RX3 | c.464_467del p.T155Rfs*10 | Frame Shift Del (DEL) | VAF 31/201 reads (15%) | called by mutect2, pindel, varscan2
- PLK5 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLXNB1 | c.344A>T p.H115L | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- RAD51AP2 | c.2909T>C p.L970S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADIPOQ | c.123G>A p.A41= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs202071028; called by muse, mutect2, varscan2
- CELSR2 | c.630G>A p.E210= | Silent (SNP) | VAF 73/446 reads (16%) | called by muse, mutect2, varscan2
- COL20A1 | c.2286G>A p.T762= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs1055660384; called by muse, mutect2, varscan2
- COL6A3 | c.6174C>T p.D2058= | Silent (SNP) | VAF 68/463 reads (15%) | catalogued as rs777351827, COSV55082401; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO46 | c.1050G>T p.A350= | Silent (SNP) | VAF 34/159 reads (21%) | catalogued as rs1568544639; called by muse, mutect2, varscan2
- GABRG1 | c.522A>G p.G174= | Silent (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- HCN1 | c.1215G>A p.R405= | Silent (SNP) | VAF 88/532 reads (17%) | catalogued as rs770503728, COSV57502478; called by muse, mutect2, varscan2
- PDE2A | c.1896C>T p.Y632= | Silent (SNP) | VAF 64/514 reads (12%) | catalogued as rs1304971837; called by muse, mutect2, varscan2
- PZP | c.330G>A p.T110= | Silent (SNP) | VAF 51/262 reads (19%) | catalogued as rs767650975, COSV54359975; called by muse, mutect2, varscan2
- SPSB3 | c.645C>T p.G215= | Silent (SNP) | VAF 86/419 reads (21%) | called by muse, mutect2, varscan2
- MTERF4 | c.*877T>G | 3'UTR (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- NSD2 | c.1675-36_1675-35insTTTTTTTTTTT | Intron (INS) | VAF 22/95 reads (23%) | called by mutect2, varscan2*
- SH3TC2 | c.3204+16A>C | Intron (SNP) | VAF 71/452 reads (16%) | called by muse, mutect2, varscan2
